CGCI case BLGSP-71-23-00408 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a826c79a-5b4a-4cb6-a919-0ab828b5c47b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 0 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Pancreas, NOS / Small intestine.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Cervical, NOS; Lymph nodes positive: 2; Lymph nodes tested: 2.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD3 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Test (IHC): Negative; Specialized molecular test: CD21.
- Lactate Dehydrogenase 738 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 90 kg; Height: 170 cm; BMI: 31.1.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00408-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-23-00408-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-23-00408-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00408-01-CD10: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-BCL6: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-CD3: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-Ki67: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-BCL2: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-CD20: Tissue microarray coordinates: C2,A3,F5.
  Slide BLGSP-71-23-00408-01-HE-1: Tissue microarray coordinates: C2,A3,F5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: pancreatic joint, duodenal; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Other pos node location: left inguinal and right cervical.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 738; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: cyclin d1.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD21.
